Surgical pathology report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE91, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE91-TTP1-A (Primary Tumor).

[page 1 of 14]
IMAGING SERVICES

[REDACTED]	Exam Date/Time:	+1403	Phone #:	[REDACTED]	MRN:	[REDACTED]
	Sex:	Male	Account #:	[REDACTED]		
	Accession #:	[REDACTED]	Performing Department:	[REDACTED]		
	Pt. Class:	Outpatient				
Primary Care Provider:		[REDACTED]				

Final - CT CHEST ABDOMEN PELVIS WO CONT [REDACTED]

Reason for Exam:

Diagnosis: Malignant neoplasm of lower third of esophagus [REDACTED]

ADDENDUM

ADDENDUM: No IV contrast was utilized.

[REDACTED]

INTERPRETATION

IMPRESSION

IMPRESSION: See report below.

Exam: CT CHEST ABDOMEN PELVIS WO CONT +1403

Date/Time of Exam: [REDACTED]

Reason For Exam: Malignant neoplasm of lower third of esophagus.
+1309 +1302

Comparison: CTA chest, [REDACTED] CT chest,
abdomen and pelvis, [REDACTED] +1115

Technique: CT of the chest, abdomen, and pelvis was performed with the administration of intravenous contrast.

Contrast: 100 mL Optiray 240 IV

Findings:

Chest:

Lower Neck: No focal masses, adenopathy, nor fluid collections.

Lungs: Areas of lucency identified involving the upper lungs consistent with COPD similar to prior exam. Fibrotic changes inferiorly again similar to prior. No focal masses or opacities.

[REDACTED]

[page 2 of 14]
Heart & Mediastinum: Heart size normal. As on prior exams there is some diffuse thickening involving the mid to distal portions of the esophagus. Lack of intravenous contrast makes evaluation for hilar and mediastinal adenopathy somewhat limited. Overall these areas appear unchanged from prior exam.

Pleural Spaces: No pleural fluid nor pneumothorax.

Chest Wall/MSK: No adenopathy nor masses. Degenerative changes thoracic spine. No lytic nor blastic lesions.

Abdomen/Pelvis:

Peritoneal Spaces: No free fluid nor gas.

Retroperitoneum/Mesentery: Normally sized vascular structures. No adenopathy, mass, nor fluid collection.

Stomach/Bowel: No obstruction. No focal inflammation. Appendix is not definitively seen but there is no focal inflammation in the cecal/right lower quadrant area.

Liver: Normal appearance.

GB/Biliary: No inflammation nor biliary dilatation.

Spleen: Normal appearance.

Pancreas: Normal appearance.

Adrenals: Normal appearance.

Kidneys, Ureters, Bladder: Normal appearance.

Pelvis: Bladder and rectum have normal appearance. No masses nor adenopathy. No focal fluid collections. Diffusely enlarged prostate again identified.

MSK/Bones: Degenerative changes lumbar spine. No lytic nor blastic lesions.

Impression:

No change in appearance of mid to distal esophagus with some diffuse thickening which may reflect scarring or some residual tumor. The lack of change would tend to argue for scarring.

Limited evaluation mediastinal lymph nodes due to lack of intravenous contrast. Overall the appearance is similar.

No acute intra-abdominal process.

[page 3 of 14]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 4 of 14]
+293

[page 5 of 14]
hydronephrosis or nephrolithiasis. There is no adenopathy in the porta hepatis, mesentery, or retroperitoneum. The abdominal aorta is normal in size. There is abundant colonic stool. The bladder is unremarkable. Prostatomegaly is noted. No bony abnormality is identified.

Impression:

1. Wall thickening in the distal esophagus appears more prominent with progression. Air-fluid level in the proximal esophagus is noted.
2. No new nodule adenopathy or mass. Please see above.

[page 6 of 14]
Results**Collection Information**Specimen 1
Collected: [REDACTED] +0Specimen Type
Other, specify [35]

Result Date [REDACTED] +490

Component ResultsComponent
PATHOLOGY/CYTOLOGY REPORT (Final)**SURGICAL PATHOLOGY FINAL REPORT****Diagnosis**

- A. Esophagus, distal, biopsy
- adenocarcinoma, moderately differentiated.
- /
- B. Stomach, biopsy
- benign gastric mucosal tissue with no significant pathologic abnormalities
- no Helicobacter-like organisms identified.
- /
- C. Small intestine, duodenal biopsy, biopsy
- normal villous architecture
- very mild chronic inflammation and eosinophilia, nonspecific.
- /
- D. Stomach, fundus, biopsy
- benign fundic-type mucosal tissue with focal foveolar dilatation.

Pathologist Comment

- B. Giemsa stain is negative for Helicobacter-like organisms.

[page 7 of 14]
Clinical Information
Rule out cancer, rule out H. pylori.

Specimen Source

A Esophagus, DISTAL
B Stomach
C Small Intestine, DUODENAL BULB
D Stomach, FUNDUS

Microscopic Description
Microscopic examination was performed.

Gross Description

Part A. Received in a container of formalin labelled [REDACTED] - mass distal esophagus" are six tan tissue fragments ranging in size from 0.2 to 0.1 cm. They are submitted entirely in A1.

Part B. Received in a container of formalin labelled [REDACTED] - gastric biopsies" are five tan tissue fragments ranging in size from 0.3 to 0.1 cm. They are submitted entirely in B1 with a Giemsa stain ordered.

Part C. Received in a container of formalin labelled [REDACTED] - duodenal bulb" are four tan tissue fragments ranging in size from 0.3 to 0.2 cm. They are submitted entirely in C1.

Part D. Received in a container of formalin labelled [REDACTED] - fundus mucosal abnormality" are three tan tissue fragments each measuring 0.2 cm. They are submitted entirely in D1.

SURGICAL PATHOLOGY ADDENDUM REPORT

Discussion
HER-2/neu analysis by immunohistochemistry was performed on block A1, with results provided in diagnostic field.

Tissue type: Distal esophagus biopsy

Diagnosis
HER2/neu result by immunohistochemistry: 1+/negative (Tumor cell cluster of 5 or more cells with faint or barely perceptible membranous reactivity irrespective of percentage of tumor cells stained)

Addendum Comment

Disclaimer:

Methodology: This analysis was performed on 10% buffered formalin-fixed paraffin-embedded tissue sections (fixation time unknown, unless stated otherwise). Antibody employed: Her-2/neu (Clone 4B5).
The customer disclaimer shown above was generated by [REDACTED]

[page 8 of 14]
[REDACTED] who is solely responsible for its content and accuracy. Some of the tests or assays being used may not be cleared or approved by the U.S. FDA. These tests were developed and their performance characteristics validated by [REDACTED]. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity laboratory testing.

Lab and Collection

PATHOLOGY [REDACTED]

Lab and Collection Informa [REDACTED]

Result History

PATHOLOGY [REDACTED]

Order Result History Repc [REDACTED]

Laboratory Information

Lab - Abbreviation

Name

Director

Address

Valid Date Range

Result Information

Status

Edited [REDACTED]

Provider Status

Reviewed

[REDACTED]

[REDACTED]

Order

PATHOLOGY [REDACTED]

Order Information

Order Placed

[REDACTED]

Order Providers

Authorizing [REDACTED]

Verbal Order Info

[REDACTED]

Original Order

Ordered On

Ordered By

Order #

[REDACTED]

Release Information

Released On

Released By

[REDACTED]

[REDACTED]

[page 9 of 14]
Order DetailsFrequency
ONE TIMEDuration
1 occurrencePriority
ROUTINEOrder Class
Unit Collect**Comments****Order Questions**

Question

of Specimens

Frozen Section

Specimen Source

Answer

04

No

Esophagus

Stomach

Duodenum

Stomach

EGD

Coml

#1 Bx's mass distal esophagus

#2 Bx's gastric

#3Bx's duodenal bulb

#4 Bx's fundus mucosal abnormality

Procedure

Order CC Information**Additional Information**

Associated Reports

View Encounter

Priority and Order Details

Collection Information

Order Requisition**Reviewed by List****Acknowledgement Info**

Acknowledged By

Acknowledged On

Order History

Inpatient

Date/Time

Action Taken

User

Additional Information

Order Tracking

View Order Tracking

[page 10 of 14]
Resu

PATHOLOGY (Order

Collect

Specimen ID

Collected: +442

Specimen Type

Other, specify [35]

Result Date +444

Component Results

Component

PATHOLOGY/CYTOLOGY REPORT (Final)

Patient:

MRN:

Accn No:

Collected:

+442

SURGICAL PATHOLOGY FINAL REPORT

Diagnosis

A. Stomach, biopsy

- benign gastric mucosa with no significant inflammation

- Giemsa stain negative for H. pylori-like organisms.

/

B. Esophagus, distal, biopsy

- recurrent adenocarcinoma, moderately differentiated.

Clinical Information

None

Specimen Source

A Stomach

B Esophagus, DISTAL

Microscopic Description

Microscopic examination was performed.

Gross Description

[page 11 of 14]
Part A. Submitted in a container of formalin labelled [REDACTED] #1 biopsy gastric" are three tan tissue fragments ranging in size from 0.2 to 0.8

cm.

The tissue is submitted entirely in A1 with a Giemsa stain ordered.

Part B. Submitted in a container of formalin labelled [REDACTED] #2 biopsy distal esophagus" are two tan-gray tissue fragments each measuring 0.3 cm. The tissue is submitted entirely in B1.

Lab and Collection

PATHOLOGY (Order [REDACTED])

Laboratory Information

Lab - Abbreviation	Name	Director	Address	Valid Date Range
--------------------	------	----------	---------	------------------

Result Information

Status	Provider Status
Final result (Collected: [REDACTED])	Reviewed
[REDACTED]	+442

Order

PATHOLOGY [REDACTED]

Order Information

Date and Time	Ordering Department	Order Placed By/Authorizing
---------------	---------------------	-----------------------------

Order Providers

Authorizing [REDACTED]

Verbal Order Info

Action	Created on	Order Mode	Entered by	Responsible Provider	Signed by	Signed on
--------	------------	------------	------------	----------------------	-----------	-----------

Original Order

Ordered On	Ordered By	Order #
------------	------------	---------

Release Information

Released On	Released By
-------------	-------------

[page 12 of 14]
Order DetailsFrequency
ONE TIMEDuration
1 occurrencePriority
ROUTINEOrder Class
Unit Collect**Comments****Order Questions**Question
of Specimens
Frozen Section
Specimen SourceAnswer
02
No
Stomach
Esophagus
egdComment

01 bxs; gastric
02; bxs; distal esophagus

Procedure

Order CC Information

Recipient

Phone

Additional InformationAssociated Reports
View Encounter
Priority and Order Details
Collection Information**Order Requisition****Reviewed By List****Acknowledgement Info**

For

At

Acknowledged By

Acknowledged On

Order History

Inpatient

Date/Time

Action Taken

User

Additional Information

Order Tracking

View Order Tracking

[page 13 of 14]
IMAGING SERVICES

Exam Date/Time:

+1857

Sex:

Male

Pt. Class:

Outpatient

Accession #:

Performing Department:

Primary Care Provider:

Ordering Provider:

Authorizing Provider:

Final - CT CHEST ABDOMEN PELVIS WO CONTRAST

Reason for Exam:

Diagnosis: Malignant neoplasm of lower third of esophagus

INTERPRETATION

IMPRESSION

IMPRESSION: Please see below.

Exam: CT CHEST ABDOMEN PELVIS WO CONTRAST

Date/Time of Exam: +1857

Reason For Exam: Malignant neoplasm of lower third of esophagus.

Technique: CT of the chest, abdomen, and pelvis was performed without the administration of intravenous contrast.

Prior exam: The prior exam is +1717

Findings: There is a right-sided Infuse-a-Port. There is no adenopathy in the axilla. Subcentimeter mediastinal lymph nodes are noted. Several 1 cm lymph nodes are noted in the aortopulmonary window. The 1.3 cm short axis lymph node in the aortopulmonary window image is also unchanged in appearance. Inferior to the carina, there is also an unchanged 1.8 cm short axis lymph node. These are unchanged. The thoracic aorta is normal in size. There is no pleural or pericardial effusion. Circumferential wall thickening is identified in the mid to distal esophagus. This is unchanged in appearance.

Severe emphysematous changes are noted. There is some dependent atelectasis. Calcified granulomas are noted. There is some mild ground-glass opacity in the lungs that may reflect some mild pneumonitis. No lobar infiltrate is identified. No discrete pulmonary nodule is identified.

The liver is homogeneous in density. The spleen, adrenal glands and pancreas are unremarkable. The gallbladder is fluid-filled. Renal vascular calcifications are noted. There is no hydronephrosis. The abdominal aorta is normal in size. There is no retrocrural or retroperitoneal adenopathy.

[page 14 of 14]
Page 2 of 2

There is a small hiatal hernia. The stomach and duodenum have an appropriate appearance. A small duodenal diverticulum is noted. There is abundant colonic stool. Diverticulosis without diverticulitis is identified. No fluid collection or inflammatory changes are identified. The bladder is unremarkable. There is prostatomegaly. Small fat-filled inguinal hernias are noted.

Osteopenia and degenerative changes are noted in the spine. No fracture or bony destructive lesion is identified.

IMPRESSION:

1. Unchanged wall thickening of the distal esophagus. Lymph nodes in the aortopulmonary window are unchanged in appearance. Emphysematous changes in the lungs are noted. No new mass or progressive adenopathy is identified. Diverticulosis without diverticulitis is identified.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0a1908d0-1bc3-415f-b9f9-18d20e82af2b (ER0413 ER-AE91 Cinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).